Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GQ-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: poor differentiated adenocarcinoma located in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: max. diameter 3.5 cm

Lymph node status: 14 lymph nodes, of which 2 contain tumor

Any comments or amendments: radical resection

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third C15.5
JW 1/28/14

Source: NCI Genomic Data Commons file 49bfb65b-8d4f-431b-b2f6-018498a6346b (TCGA-2H-A9GQ.71956D07-B894-4552-82A0-9606DE238867.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).